Somatic mutation profile of cancer-model specimen HCM-CSHL-0598-C25-85B (3D Organoid; aliquot HCM-CSHL-0598-C25-85B-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0598-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 57.1 years (20,872 days).
Specimen HCM-CSHL-0598-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2db9bd0-e90b-450a-a254-5f8e1a322faf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0598-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0598-C25-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03d88c22-e8fa-4071-9c6e-e7d154501d9c

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, Frame Shift Del 3, Intron 3, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.1113del p.Q372Sfs*19 | Frame Shift Del (DEL) | VAF 163/394 reads (41%) | catalogued as rs875989848; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 227/516 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 258/259 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATAD3A | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 121/257 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278574100; called by muse, mutect2, varscan2
- BASP1 | c.360_386del p.K121_P129del | In Frame Del (DEL) | VAF 198/490 reads (40%) | catalogued as rs1198203139; called by mutect2, pindel, varscan2
- CD248 | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 235/648 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.919); catalogued as rs539641105, COSV60935987; called by muse, mutect2
- CORIN | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs767748016; called by muse, varscan2
- CPXCR1 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV52161262; called by muse, mutect2, varscan2
- DIS3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 130/461 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146500302, COSV66707916; called by muse, mutect2, varscan2
- EIF2D | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 93/364 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs34138767, COSV55113559; called by muse, mutect2, varscan2
- EIF3F | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 100/302 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753765986; called by muse, mutect2, varscan2
- EML4 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 131/430 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760285260; called by muse, mutect2, varscan2
- GJA8 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 134/512 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1237822086; called by muse, mutect2, varscan2
- IFT172 | c.5005G>A p.A1669T | Missense Mutation (SNP) | VAF 202/571 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs146575848; called by muse, mutect2, varscan2
- KCNB2 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 110/281 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.836); catalogued as rs1427766547; called by muse, mutect2, varscan2
- LARGE2 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 46/776 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs377634656; called by muse, mutect2
- MRPL27 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 113/401 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs566987704; called by muse, varscan2
- MYH9 | c.5647G>A p.E1883K | Missense Mutation (SNP) | VAF 40/1056 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1261555310; called by muse, mutect2
- NID1 | c.1855G>A p.V619I | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs148420954; called by muse, varscan2
- NPC1 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 134/472 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV52578851; called by muse, varscan2
- PHF20 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 174/501 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as rs770122276; called by muse, mutect2, varscan2
- PRDM9 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 189/430 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1450853481, COSV57004243; called by muse, varscan2
- SEC24D | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771020078; called by muse, mutect2, varscan2
- SLC8A1 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 197/312 reads (63%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.776); catalogued as rs756189297, COSV60481812; called by muse, mutect2, varscan2
- SSH1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 137/304 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs760151045, COSV58458613, COSV99044341; called by muse, mutect2, varscan2
- WBP2NL | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 295/563 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs752029730; called by muse, mutect2, varscan2
- ZBED2 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 124/479 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1008453412; called by muse, mutect2, varscan2
- ZNF831 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 227/665 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs756858166, COSV64042054; called by muse, mutect2, varscan2
- ACTL7B | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 183/647 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGRN | c.4123C>T p.P1375S | Missense Mutation (SNP) | VAF 170/353 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2
- AP002748.5 | c.911G>A p.C304Y | Missense Mutation (SNP) | VAF 115/419 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC91 | c.73_75del p.T25del | In Frame Del (DEL) | VAF 72/414 reads (17%) | called by pindel, varscan2
- CLCA2 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 169/320 reads (53%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNIH2 | c.151-1G>T p.X51_splice | Splice Site (SNP) | VAF 22/405 reads (5%) | called by muse, mutect2
- CRMP1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 49/496 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- DAZL | c.305del p.N102Ifs*7 | Frame Shift Del (DEL) | VAF 35/135 reads (26%) | called by mutect2, pindel, varscan2
- DCAF13 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 157/585 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO36 | c.129G>C p.R43S | Missense Mutation (SNP) | VAF 117/339 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIFC3 | c.95T>A p.M32K | Missense Mutation (SNP) | VAF 61/982 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.599); called by muse, mutect2
- KRTAP5-9 | c.200del p.G67Afs*112 | Frame Shift Del (DEL) | VAF 386/743 reads (52%) | called by mutect2, pindel, varscan2
- LPIN2 | c.1360A>G p.S454G | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC74B | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 1006/1860 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- LRRC74B | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 615/1079 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PHF20L1 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 83/572 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- RELN | c.7427A>T p.Y2476F | Missense Mutation (SNP) | VAF 168/476 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ZXDB | c.911T>G p.F304C | Missense Mutation (SNP) | VAF 280/283 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AADAT | c.1167C>T p.V389= | Silent (SNP) | VAF 85/200 reads (43%) | catalogued as rs1054031905, COSV61787627; called by muse, mutect2, varscan2
- APOL5 | c.1301G>A p.*434= | Silent (SNP) | VAF 94/396 reads (24%) | catalogued as COSV99968315; called by muse, mutect2, varscan2
- BSN | c.2436C>T p.H812= | Silent (SNP) | VAF 384/632 reads (61%) | catalogued as rs754219572, COSV56521041; called by muse, mutect2, varscan2
- CDK5R1 | c.672C>T p.A224= | Silent (SNP) | VAF 34/550 reads (6%) | catalogued as COSV55579373; called by muse, mutect2
- HIF3A | c.1164C>T p.I388= (on ENST00000377670 / NM_152795.4; = p.I319= on NM_022462.4) | Silent (SNP) | VAF 145/551 reads (26%) | called by muse, mutect2, varscan2
- KIAA0100 | c.4467G>A p.K1489= | Silent (SNP) | VAF 160/493 reads (32%) | called by muse, mutect2, varscan2
- MUC4 | c.15696C>T p.V5232= (on ENST00000463781 / NM_018406.7; = p.V996= on NM_004532.6) | Silent (SNP) | VAF 119/825 reads (14%) | catalogued as rs1325328057; called by muse, mutect2, varscan2
- OR10J1 | c.474G>A p.T158= | Silent (SNP) | VAF 129/443 reads (29%) | catalogued as rs149860482, COSV71128517; called by muse, mutect2, varscan2
- QSOX1 | c.2220C>A p.G740= | Silent (SNP) | VAF 141/512 reads (28%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.750C>T p.S250= | Silent (SNP) | VAF 90/402 reads (22%) | catalogued as rs745563782, COSV58432366; called by muse, mutect2
- SKIDA1 | c.1671C>T p.H557= | Silent (SNP) | VAF 115/356 reads (32%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.1410C>T p.C470= | Silent (SNP) | VAF 268/432 reads (62%) | catalogued as rs752840486; called by muse, mutect2, varscan2
- SPATA31D1 | c.153G>A p.S51= | Silent (SNP) | VAF 153/360 reads (43%) | catalogued as rs774360466, COSV61195517; called by muse, mutect2, varscan2
- SURF2 | c.6C>T p.S2= | Silent (SNP) | VAF 40/694 reads (6%) | catalogued as rs587703175; called by muse, mutect2
- SYNE1 | c.14322A>G p.E4774= (on ENST00000367255 / NM_182961.4; = p.E4703= on NM_033071.3) | Silent (SNP) | VAF 140/303 reads (46%) | called by muse, mutect2, varscan2
- TBC1D28 | c.435C>T p.I145= | Silent (SNP) | VAF 130/299 reads (43%) | called by muse, mutect2, varscan2
- TMEM192 | c.12G>T p.G4= | Silent (SNP) | VAF 55/505 reads (11%) | catalogued as COSV100122078; called by muse, mutect2, varscan2
- ZNF461 | c.1173G>A p.G391= | Silent (SNP) | VAF 101/431 reads (23%) | called by muse, mutect2, varscan2
- TEX35 | c.586+408C>T | Intron (SNP) | VAF 293/440 reads (67%) | catalogued as rs375665900; called by muse, mutect2, varscan2
- TJP1 | c.1010+862_1010+868del | Intron (DEL) | VAF 61/358 reads (17%) | called by mutect2, pindel, varscan2
- TTN | c.34265-3000C>T | Intron (SNP) | VAF 83/261 reads (32%) | catalogued as rs1384874573; called by muse, mutect2, varscan2
